Somatic mutation profile of tumor specimen TCGA-UB-AA0U-01A (aliquot TCGA-UB-AA0U-01A-11D-A382-10) from TCGA case TCGA-UB-AA0U, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.2 years (21,985 days).
Specimen TCGA-UB-AA0U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44fc9259-cf8b-4bb4-9f43-db9960605e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-AA0U-10A (Blood Derived Normal), aliquot TCGA-UB-AA0U-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ef01239-c970-4d42-a491-ef186dbf03a4

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 26, In Frame Del 4, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, Translation Start Site 1, In Frame Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP22 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as rs768138963, COSV50939937, COSV99985569; called by muse, mutect2, varscan2
- ARID2 | c.4773+1G>T p.X1591_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100536939, COSV57609943; called by muse, mutect2, varscan2
- ARMC4 | c.2381G>T p.R794L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100537052; called by muse, mutect2, varscan2
- ASXL2 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV99711542; called by muse, mutect2, varscan2
- BRD8 | c.3644A>G p.K1215R | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99496873; called by muse, mutect2, varscan2
- C17orf64 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as rs756200782, COSV52258449; called by muse, mutect2, varscan2
- C1orf35 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.08); catalogued as COSV99683258; called by mutect2, varscan2
- CD1A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs139349958; called by muse, mutect2, varscan2
- CDHR2 | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99991813; called by muse, mutect2, varscan2
- CHRM4 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs1307085161, COSV100708818; called by muse, mutect2, varscan2
- COL22A1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279115; called by muse, mutect2, varscan2
- COL22A1 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377284965, COSV100279117; called by muse, mutect2, varscan2
- DAB2 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100298127; called by muse, mutect2, varscan2
- DLL1 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs780734657, COSV64537468; called by muse, mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DSCAM | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101260660; called by muse, mutect2, varscan2
- ERBB4 | c.3419G>T p.S1140I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100726322, COSV104418389; called by muse, mutect2, varscan2
- FBXO15 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.056); catalogued as rs772944634, COSV99503484; called by muse, mutect2, varscan2
- FOSL2 | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV99268421; called by muse, mutect2, varscan2
- GPAA1 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554764373, COSV100731177; called by muse, mutect2, varscan2
- GPX6 | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1295128498, COSV100724871; called by muse, mutect2
- GRIA4 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as COSV99232621; called by muse, mutect2, varscan2
- GRIP1 | c.2240T>C p.V747A (on ENST00000359742 / NM_001379345.1; = p.V695A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV99669980; called by muse, mutect2, varscan2
- GSE1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs374600357; called by muse, mutect2, varscan2
- HECTD4 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66394569; called by muse, mutect2, varscan2
- IDH1 | c.890G>C p.C297S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100577029; called by muse, mutect2, varscan2
- IL1RL2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV99960829; called by muse, mutect2, varscan2
- KIAA1217 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs754656050, COSV64601592, COSV64611067; called by muse, mutect2, varscan2
- KIT | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55391342; called by muse, mutect2, varscan2
- KRTAP4-1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100893564; called by muse, mutect2, varscan2
- LMBR1L | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV57267625; called by muse, mutect2, varscan2
- MAGEC3 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100025676; called by muse, mutect2, varscan2
- MAP3K2 | c.478A>G p.R160G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as rs767432874, COSV100789360; called by muse, mutect2, varscan2
- MATN4 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | PolyPhen probably damaging (0.983); catalogued as rs1044592691, COSV100637085; called by muse, mutect2, varscan2
- MECOM | c.338A>T p.N113I (on ENST00000468789 / NM_001105078.4; = p.N301I on NM_004991.4) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427543297, COSV99244889; called by muse, mutect2, varscan2
- MMP12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200973192, COSV100404873; called by muse, mutect2, varscan2
- MYT1L | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101221027; called by muse, mutect2, varscan2
- NIPAL2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57837838; called by muse, mutect2, varscan2
- ODAPH | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100290215; called by muse, mutect2, varscan2
- OR14K1 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs1177022710, COSV99315293; called by muse, mutect2, varscan2
- OR5V1 | c.197T>G p.L66W | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011347; called by muse, mutect2, varscan2
- PROSER1 | c.1517A>G p.Q506R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV100612867; called by muse, mutect2, varscan2
- RDH8 | c.475G>A p.V159M (on ENST00000651512; = p.V139M on NM_015725.4) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99408723; called by muse, mutect2, varscan2
- REV3L | c.5065C>A p.Q1689K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100725348; called by muse, mutect2, varscan2
- RNF121 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV100683576; called by muse, mutect2, varscan2
- RRM1 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.026); catalogued as COSV100331351; called by muse, mutect2, varscan2
- SCARF1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.4); catalogued as rs1158791589, COSV99557142; called by muse, mutect2, varscan2
- SLC4A3 | c.2789T>A p.F930Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99812974; called by muse, mutect2, varscan2
- SMARCA4 | c.3340G>A p.D1114N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758731, COSV60785929; called by muse, mutect2, varscan2
- SPAM1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99773165; called by muse, mutect2, varscan2
- SPTAN1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100823740; called by muse, mutect2, varscan2
- TECPR2 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.427); catalogued as rs1214655550, COSV100850082; called by muse, mutect2, varscan2
- THSD7B | c.2743C>G p.L915V | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1226457331, COSV55700991, COSV99753563; called by muse, mutect2
- TNFSF15 | c.558C>G p.D186E | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs750502102, COSV100928328; called by muse, mutect2, varscan2
- TRERF1 | c.2867A>T p.E956V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV100551009; called by muse, varscan2
- USP5 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV57536019, COSV57536491, COSV99978802; called by muse, mutect2, varscan2
- WDR12 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99651162; called by muse, mutect2, varscan2
- XRCC5 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as COSV101079682; called by muse, mutect2, varscan2
- IGKV1-27 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KCNE3 | c.289_300del p.K97_V100del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- MBL2 | c.529_564del p.L177_D188del | In Frame Del (DEL) | VAF 39/129 reads (30%) | called by mutect2, pindel
- MC1R | c.790_798del p.I264_L266del | In Frame Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- MYRF | c.344dup p.T118Hfs*8 (on ENST00000278836 / NM_001127392.3; = p.T109Hfs*8 on NM_013279.4) | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- OR4B1 | c.623_625del p.S208del | In Frame Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- RBL2 | c.1828dup p.R610Kfs*4 | Frame Shift Ins (INS) | VAF 85/191 reads (45%) | called by mutect2, pindel, varscan2
- SATL1 | c.887_894del p.E296Afs*62 (on ENST00000395409; = p.E483Afs*62 on NM_001012980.2) | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- TDRD1 | c.2323_2323+10del p.X775_splice | Splice Site (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel
- USP6NL | c.1270_1272dup p.T424dup | In Frame Ins (INS) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- AC004997.1 | c.783T>G p.A261= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99304730; called by muse, varscan2
- ACLY | c.2628C>T p.L876= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100709758; called by muse, mutect2, varscan2
- ADCY5 | c.609G>A p.L203= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV101518447; called by muse, mutect2, varscan2
- ALDH1B1 | c.1068C>T p.T356= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as rs1391603644, COSV100890956; called by muse, mutect2, varscan2
- ALG9 | c.1488T>A p.G496= (on ENST00000614444 / NM_001352418.1; = p.G503= on NM_024740.2) | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV101211922; called by muse, mutect2, varscan2
- CATSPER1 | c.2032C>T p.L678= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100376059; called by muse, mutect2, varscan2
- DCT | c.1077G>A p.G359= | Silent (SNP) | VAF 38/257 reads (15%) | catalogued as COSV100986254; called by muse, mutect2, varscan2
- DPP8 | c.384A>G p.L128= (on ENST00000341861 / NM_001320875.2; = p.L112= on NM_017743.6) | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100202449; called by muse, mutect2, varscan2
- FLNC | c.1014C>A p.V338= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100368336; called by muse, mutect2, varscan2
- GAA | c.2682T>C p.S894= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100163353; called by muse, mutect2, varscan2
- GNAZ | c.603C>T p.D201= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs375941406; called by muse, mutect2, varscan2
- KRTAP5-5 | c.183C>G p.G61= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV101294185; called by muse, mutect2, varscan2
- LGR5 | c.1758T>G p.P586= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV99878090; called by muse, mutect2, varscan2
- MCF2L | c.2493G>A p.L831= (on ENST00000375608; = p.L799= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99995931; called by muse, mutect2
- MDN1 | c.12171G>A p.L4057= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs773169417, COSV101021527, COSV65527265; called by muse, mutect2, varscan2
- MNS1 | c.603A>G p.K201= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99549683; called by mutect2, varscan2
- NLRP3 | c.2739G>A p.T913= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs201764635, COSV100276286; called by muse, mutect2, varscan2
- NLRP6 | c.642G>A p.K214= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100381057; called by muse, mutect2, varscan2
- PCDH18 | c.1494G>A p.G498= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100787396; called by muse, varscan2
- PRR11 | c.54A>G p.L18= | Silent (SNP) | VAF 94/311 reads (30%) | catalogued as rs943105265, COSV99231622; called by mutect2, varscan2
- RASA1 | c.864A>G p.L288= | Silent (SNP) | VAF 90/275 reads (33%) | catalogued as rs777884338, COSV99170045; ClinVar: likely benign; called by muse, mutect2, varscan2
- THAP9 | c.564A>T p.L188= | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as COSV100155899; called by muse, mutect2, varscan2
- TMEM62 | c.1560A>G p.G520= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs778586768, COSV99543720; called by muse, mutect2, varscan2
- TRIM42 | c.1116G>A p.K372= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as rs1246150462, COSV99648520; called by muse, mutect2, varscan2
- TRIM72 | c.375C>T p.A125= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs553041719, COSV100265436; called by muse, mutect2, varscan2
- ZRANB3 | c.1281A>G p.A427= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs1299824162, COSV99924028; called by muse, mutect2, varscan2
- ABLIM1 | c.1441+2582G>C | Intron (SNP) | VAF 32/130 reads (25%) | called by muse, mutect2, varscan2
